Somatic mutation profile of tumor specimen MP2PRT-PASSHT-TMP1-A (aliquot MP2PRT-PASSHT-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASSHT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,504 days).
Specimen MP2PRT-PASSHT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cff2b88-d87b-43ab-8922-c22d02ff3f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSHT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSHT-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/933dd495-9030-4368-9a28-9005f6d8b03c

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.5320T>G p.F1774V | Missense Mutation (SNP) | VAF 138/523 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV99797652; called by muse, mutect2, varscan2
- ANK2 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 118/400 reads (30%) | catalogued as rs1554508985, COSV52154619, COSV52189578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD10 | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 175/513 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs775615805; called by muse, mutect2, varscan2
- COL22A1 | c.4394G>A p.R1465H | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373788593, COSV57331718, COSV57354543; called by muse, mutect2, varscan2
- DMBX1 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 31/446 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs200058413; called by muse, mutect2
- EIF4A1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51511043; called by muse, mutect2, varscan2
- EZH2 | c.2069C>T p.S690L (on ENST00000460911 / NM_001203247.2; = p.S695L on NM_004456.5) | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM1110543, COSV57449243; called by muse, mutect2, varscan2
- KCNQ4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 175/612 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs1428248589, COSV61275670; called by muse, mutect2, varscan2
- MAMDC4 | c.3269G>A p.R1090Q (on ENST00000445819; = p.R1011Q on NM_206920.3) | Missense Mutation (SNP) | VAF 108/403 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs757957683; called by muse, mutect2, varscan2
- RHOBTB1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.105); catalogued as rs749464528; called by muse, mutect2, varscan2
- TOGARAM2 | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 151/552 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs376723895; called by muse, mutect2, varscan2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 223/556 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LEF1 | c.1065_1068del p.E355Dfs*39 | Frame Shift Del (DEL) | VAF 41/366 reads (11%) | called by pindel, varscan2
- PRR32 | c.738T>A p.C246* | Nonsense Mutation (SNP) | VAF 218/808 reads (27%) | called by muse, mutect2, varscan2
- SATL1 | c.334G>A p.A112T (on ENST00000395409; = p.A299T on NM_001012980.2) | Missense Mutation (SNP) | VAF 195/672 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SBF2 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A4 | c.1366T>C p.F456L (on ENST00000264485 / NM_001098484.3; = p.F412L on NM_003759.4) | Missense Mutation (SNP) | VAF 107/391 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SULT2B1 | c.841T>A p.W281R (on ENST00000201586 / NM_177973.2; = p.W266R on NM_004605.2) | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF280C | c.31A>C p.N11H | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ADGRL3 | c.960C>A p.T320= (on ENST00000506720 / NM_001322402.2; = p.T252= on NM_015236.6) | Silent (SNP) | VAF 124/441 reads (28%) | called by muse, mutect2, varscan2
- COL21A1 | c.1242G>A p.Q414= | Silent (SNP) | VAF 119/419 reads (28%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1314C>T p.A438= | Silent (SNP) | VAF 139/512 reads (27%) | called by muse, mutect2, varscan2
- GRAMD4 | c.357G>A p.Q119= | Silent (SNP) | VAF 88/299 reads (29%) | catalogued as rs1178325808; called by muse, varscan2
- SOCS3 | c.162C>T p.G54= | Silent (SNP) | VAF 179/659 reads (27%) | called by muse, mutect2, varscan2
- ZNF451 | c.387A>C p.A129= | Silent (SNP) | VAF 114/425 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916468 C>T | 5'Flank (SNP) | VAF 189/654 reads (29%) | catalogued as COSV58121664; called by muse, mutect2, varscan2
- DST | c.4297-2376G>A | Intron (SNP) | VAF 115/423 reads (27%) | catalogued as rs750599278, COSV55012166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
